Somatic mutation profile of tumor specimen TARGET-30-PASZGB-01A (aliquot TARGET-30-PASZGB-01A-01D) from TARGET case TARGET-30-PASZGB, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.3 years (458 days).
Specimen TARGET-30-PASZGB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb6d15ef-fae3-48ec-a05b-467e57d83420.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASZGB-10A (Blood Derived Normal), aliquot TARGET-30-PASZGB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a67b3e41-fd8f-452c-9790-1f90f6ee0eab

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.2731G>T p.A911S | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV53772305; called by muse, mutect2, varscan2
- MAD1L1 | c.1563G>T p.M521I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1B | c.2840+2328G>A | Intron (SNP) | VAF 71/247 reads (29%) | catalogued as COSV51679321; called by muse, mutect2, varscan2
- NF1 | c.*2307C>A | 3'UTR (SNP) | VAF 57/193 reads (30%) | catalogued as COSV62220163; called by muse, mutect2
- NPAP1 | c.*1328C>T | 3'UTR (SNP) | VAF 28/75 reads (37%) | catalogued as rs778940292, COSV61510797; called by muse, mutect2, varscan2
- VANGL1 | chr1:115692093 G>T | 3'Flank (SNP) | VAF 36/105 reads (34%) | catalogued as COSV59622237; called by muse, mutect2, varscan2
